Somatic mutation profile of tumor specimen TCGA-AR-A24K-01A (aliquot TCGA-AR-A24K-01A-11D-A167-09) from TCGA case TCGA-AR-A24K, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.4 years (16,961 days).
Specimen TCGA-AR-A24K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e86f859-0c03-4330-9927-941c8b3090fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24K-10A (Blood Derived Normal), aliquot TCGA-AR-A24K-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcda65cd-6506-4751-b0fe-cac24d3b9ecf

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA8 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV52193724; called by muse, mutect2, varscan2
- CCER1 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62645827; called by muse, mutect2, varscan2
- CHST8 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52855988; called by muse, mutect2, varscan2
- EEF2 | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58578486, COSV58578828; called by muse, mutect2, varscan2
- EGF | c.3193A>G p.K1065E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV54475408; called by muse, mutect2, varscan2
- IGDCC3 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV60076346; called by muse, mutect2, varscan2
- KCNH8 | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.08); catalogued as rs1193045273, COSV60456013; called by muse, mutect2, varscan2
- MET | c.2335G>A p.V779M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1562923583, COSV59256509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOR1 | c.4513+2T>C p.X1505_splice | Splice Site (SNP) | VAF 25/35 reads (71%) | catalogued as COSV99248333; called by muse, mutect2, varscan2
- NFKBIB | c.621C>A p.G207= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100548320; called by muse, mutect2
- PADI6 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV61883668; called by muse, mutect2, varscan2
- PI15 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs200651515, COSV52639480; called by muse, mutect2, varscan2
- PRKCD | c.1573T>A p.Y525N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57846579; called by muse, mutect2, varscan2
- RRBP1 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV55695385; called by muse, mutect2, varscan2
- SPTBN2 | c.4784G>A p.R1595H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs763501939, COSV59446250; called by muse, mutect2, varscan2
- STAB2 | c.4138G>A p.G1380S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758321674, COSV66333760, COSV66345298; called by muse, mutect2, varscan2
- TMTC2 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1341846388, COSV58258896, COSV58284464; called by muse, mutect2, varscan2
- TOMM40 | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99376004; called by muse, mutect2
- TP53 | c.325_326dup p.R110Sfs*14 | Frame Shift Ins (INS) | VAF 17/24 reads (71%) | catalogued as COSV52810245, COSV53186151; called by mutect2, pindel, varscan2
- TRPS1 | c.1592G>A p.R531Q (on ENST00000220888 / NM_001330599.2; = p.R544Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs769392409, COSV55266120; called by muse, mutect2, varscan2
- VCL | c.692A>G p.N231S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1194024528, COSV53006830; called by muse, mutect2, varscan2
- VN1R4 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV60804578; called by muse, mutect2, varscan2
- CYP2S1 | c.543A>T p.V181= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV59504937; called by muse, mutect2, varscan2
- LIPT1 | c.507C>T p.I169= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs1000186375, COSV60739192; called by muse, mutect2, varscan2
- LRGUK | c.765A>G p.L255= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV53633852; called by muse, mutect2, varscan2
- MPV17L2 | c.243G>A p.L81= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV55851815; called by muse, mutect2, varscan2
- SLC12A9 | c.705G>T p.R235= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99307609; called by muse, mutect2
